Somatic mutation profile of tumor specimen TARGET-10-PANXCX-09A (aliquot TARGET-10-PANXCX-09A-01D) from TARGET case TARGET-10-PANXCX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (922 days).
Specimen TARGET-10-PANXCX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3772193f-f08a-44dd-b1ef-2bca41e45411.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANXCX-10A (Blood Derived Normal), aliquot TARGET-10-PANXCX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a11508d7-bbe5-462f-ac4e-1beab70fc480

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HOXB8 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99032484; called by muse, mutect2, varscan2
- TRIM10 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs367573300; called by muse, mutect2, varscan2
- JUP | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KSR2 | c.2521T>C p.S841P | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); called by muse, mutect2
- TACR3 | c.1143C>A p.S381R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TRAFD1 | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBASH3A | c.1154G>A p.S385N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MINDY4B | c.1240+23G>T | Intron (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- NF1 | c.6705-19G>C | Intron (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- PON1 | c.*7G>A | 3'UTR (SNP) | VAF 10/115 reads (9%) | catalogued as rs1361556248, COSV99195199; called by muse, mutect2
